Somatic mutation profile of tumor specimen MBCProject_2346_T3_WES (aliquot MBCProject_2346_T3_WES_1) from CMI case MBCProject_2346, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 45.8 years (16,733 days).
Specimen MBCProject_2346_T3_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Soft Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 193028ed-4831-48ad-9f1c-45b907b76822.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_2346_SALIVA (Saliva), aliquot MBCProject_2346_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/213fca02-6031-4e32-bfcd-eeb6c3120237

The open-access MAF lists 35 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 7, Intron 3, Splice Region 1, Frame Shift Del 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 25/298 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- PIK3CA | c.3145G>C p.G1049R | Missense Mutation (SNP) | VAF 13/98 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.096); catalogued as rs121913277, CM126700, COSV55874453, COSV55878564, COSV55919873; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.903C>G p.Y301* | Nonsense Mutation (SNP) | VAF 40/682 reads (6%) | catalogued as rs746084369; ClinVar: pathogenic; called by muse, mutect2
- ARHGAP18 | c.1045C>T p.L349= | Splice Region (SNP) | VAF 17/240 reads (7%) | catalogued as rs577421005; called by muse, mutect2
- CKM | c.1102G>C p.E368Q | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV53465517; called by muse, mutect2, varscan2
- DACT3 | c.1808T>A p.V603E | Missense Mutation (SNP) | VAF 25/470 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100340470; called by muse, mutect2
- HSD17B3 | c.894C>A p.H298Q | Missense Mutation (SNP) | VAF 31/493 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV64558508; called by muse, mutect2
- MPDZ | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as COSV100063037; called by muse, mutect2
- MYH11 | c.5218C>G p.Q1740E | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as COSV100257650; called by muse, mutect2
- OR4A16 | c.796G>C p.D266H | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100125205; called by muse, mutect2
- SETD5 | c.4277G>A p.R1426Q | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0.068); catalogued as rs757364157; called by muse, mutect2
- WFDC3 | c.163A>C p.K55Q | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV54784172; called by muse, mutect2
- AFP | c.1458C>G p.I486M | Missense Mutation (SNP) | VAF 23/298 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.789); called by muse, mutect2
- ASRGL1 | c.876G>C p.K292N | Missense Mutation (SNP) | VAF 28/568 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.009); called by muse, mutect2
- CYP4B1 | c.419T>G p.L140R | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- DCLK1 | c.2015_2030del p.G672Afs*9 | Frame Shift Del (DEL) | VAF 16/194 reads (8%) | called by mutect2, pindel
- EFR3A | c.221T>A p.V74D | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FAM110B | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 28/287 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FREM2 | c.7402G>T p.D2468Y | Missense Mutation (SNP) | VAF 26/389 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HBM | c.298-2A>G p.X100_splice | Splice Site (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- HERC2 | c.12139G>A p.G4047R | Missense Mutation (SNP) | VAF 28/372 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- NUTM2E | c.2530G>A p.G844R | Missense Mutation (SNP) | VAF 17/287 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); called by muse, mutect2
- PKD1 | c.4413C>G p.I1471M | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PRPF8 | c.2047C>G p.L683V | Missense Mutation (SNP) | VAF 23/424 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.122); called by muse, mutect2
- RAB3D | c.634C>G p.P212A | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- CIRBP | c.309C>T p.F103= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as rs1396484444; called by muse, mutect2
- ETV2 | c.792C>T p.G264= | Silent (SNP) | VAF 22/259 reads (8%) | called by muse, mutect2
- FCGBP | c.11574C>A p.P3858= | Silent (SNP) | VAF 15/114 reads (13%) | called by muse, mutect2
- MAGEA8 | c.186C>T p.P62= | Silent (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2
- SACS | c.2880G>A p.L960= | Silent (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- SI | c.1044A>T p.P348= | Silent (SNP) | VAF 26/320 reads (8%) | called by muse, mutect2
- TUBB2B | c.309G>A p.K103= | Silent (SNP) | VAF 18/396 reads (5%) | catalogued as rs1271743963; called by muse, mutect2
- ARHGEF3 | c.62+27756G>T | Intron (SNP) | VAF 57/353 reads (16%) | called by muse, mutect2, varscan2
- DOCK9 | c.5367+24G>A | Intron (SNP) | VAF 15/210 reads (7%) | called by muse, mutect2
- MDGA2 | c.1525+1915A>G | Intron (SNP) | VAF 12/205 reads (6%) | called by muse, mutect2
